Somatic mutation profile of tumor specimen TCGA-DX-AB2J-01A (aliquot TCGA-DX-AB2J-01A-11D-A387-09) from TCGA case TCGA-DX-AB2J, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 71.6 years (26,154 days).
Specimen TCGA-DX-AB2J-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 544de935-4d19-465b-ae70-bc34c70222e8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-AB2J-10A (Blood Derived Normal), aliquot TCGA-DX-AB2J-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/020594c3-b71c-4dc6-aec7-4f393f075059

The open-access MAF lists 29 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SF3B1 | c.2098A>G p.K700E | Missense Mutation (SNP) | VAF 14/33 reads (42%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs559063155, COSV59205318, COSV59216586; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AP000311.1 | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 24/67 reads (36%) | SIFT deleterious, low confidence (0); catalogued as COSV99285553; called by muse, mutect2, varscan2
- COL19A1 | c.349T>C p.W117R | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100506490; called by muse, mutect2
- COQ8B | c.818G>C p.S273T | Missense Mutation (SNP) | VAF 31/70 reads (44%) | SIFT tolerated (0.3); PolyPhen benign (0.036); catalogued as COSV99699462; called by muse, mutect2, varscan2
- DCAF12L1 | c.579C>A p.H193Q | Missense Mutation (SNP) | VAF 88/181 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100948334; called by muse, mutect2, varscan2
- DZIP3 | c.1090A>G p.I364V | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT tolerated, low confidence (0.75); PolyPhen benign (0.003); catalogued as COSV100847848; called by muse, mutect2, varscan2
- GRIN1 | c.323C>T p.S108F | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100160389; called by muse, mutect2, varscan2
- IFT172 | c.2404A>G p.I802V | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT tolerated (0.71); PolyPhen benign (0.067); catalogued as COSV99562635; called by muse, mutect2, varscan2
- MAP7D1 | c.1474C>A p.P492T | Missense Mutation (SNP) | VAF 19/42 reads (45%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV100294560, COSV60217160; called by muse, mutect2, varscan2
- NFE2L3 | c.1596_1599del p.D532Efs*3 | Frame Shift Del (DEL) | VAF 28/85 reads (33%) | catalogued as rs867593033; called by mutect2, pindel, varscan2
- OBSL1 | c.782A>G p.K261R | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs752822770, COSV54726009; called by muse, mutect2, varscan2
- PAIP1 | c.1138G>C p.V380L | Missense Mutation (SNP) | VAF 51/115 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV100166624; called by muse, mutect2, varscan2
- PDE3B | c.3264A>T p.K1088N | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); catalogued as COSV99962680; called by muse, mutect2, varscan2
- RAD54L2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1559646800, COSV56578104; called by muse, mutect2
- SIGLEC6 | c.1013-1G>A p.X338_splice | Splice Site (SNP) | VAF 32/80 reads (40%) | catalogued as COSV100585466; called by muse, mutect2, varscan2
- SMAD3 | c.791C>T p.S264F | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100528546, COSV100529104; called by muse, mutect2, varscan2
- SPAG11B | c.127G>T p.A43S | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT tolerated, low confidence (0.6); PolyPhen probably damaging (0.983); catalogued as COSV99873065; called by mutect2, varscan2
- TG | c.7042G>A p.G2348R | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT tolerated (0.21); PolyPhen benign (0.131); catalogued as rs755059149, COSV55085200; called by muse, mutect2, varscan2
- TMEM255A | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs921853112, COSV100550405; called by muse, mutect2, varscan2
- VPS13B | c.6223A>G p.S2075G | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as COSV100662301; called by muse, mutect2, varscan2
- VSTM2A | c.575C>T p.T192M | Missense Mutation (SNP) | VAF 31/53 reads (58%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs144355001; called by muse, mutect2, varscan2
- CREBBP | c.543del p.F181Lfs*17 | Frame Shift Del (DEL) | VAF 36/83 reads (43%) | called by mutect2, pindel, varscan2
- RPL11 | c.4_6+13del p.X2_splice | Splice Site (DEL) | VAF 15/39 reads (38%) | called by mutect2, pindel, varscan2
- TRAV12-2 | c.155A>T p.Q52L | Missense Mutation (SNP) | VAF 29/71 reads (41%) | SIFT tolerated (0.09); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- BAZ2A | c.5316A>C p.A1772= | Silent (SNP) | VAF 20/76 reads (26%) | catalogued as COSV99466517; called by muse, mutect2, varscan2
- MFSD5 | c.510C>G p.T170= | Silent (SNP) | VAF 18/92 reads (20%) | catalogued as COSV100289071; called by muse, mutect2, varscan2
- MMGT1 | c.291T>A p.G97= | Silent (SNP) | VAF 25/59 reads (42%) | catalogued as COSV100018555; called by muse, mutect2, varscan2
- NCOA1 | c.4137A>C p.T1379= | Silent (SNP) | VAF 31/66 reads (47%) | catalogued as COSV99946311; called by muse, mutect2, varscan2
- PNPLA6 | c.3384C>T p.D1128= (on ENST00000414982 / NM_001166111.2; = p.D1080= on NM_006702.5) | Silent (SNP) | VAF 74/152 reads (49%) | catalogued as rs765884981, COSV55383429; called by muse, mutect2, varscan2
